Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A8MW, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A8MW-01A (Primary Tumor).

[page 1 of 3]
FILE IN PATIENT HISTORY

Patient Location

Name

Given Name

DOB

Patient Address

Sex M

Tel:

Consultant

FILE IN PATIENT HISTORY

Adenocarcinoma, intestinal type 814413
Adenocarcinoma NOS 814013
Site: Gastric antrum

HISTOPATHOLOGY REPORT

QV 3/28/14

Biopsy No
Received
Lab No
Collected

CLINICAL NOTES

Ulcerative lesion antrum-pylorus. 5cm Ca. Tiny ascending colon polyp.
Stomach (body), antral tumour and asc colon polyp.

MACROSCOPY

1. Labelled "gastric bx". A tan tissue fragment 3 x 3mm. A1.
2. Labelled "gastric tumour". Multiple tan tissue fragments 15 x 10mm in aggregate. A1.
3. Labelled "ascending colon polyp". A tan tissue fragment 2 x 1mm. A1.

MICROSCOPY

1. There is a single fragment of acid-secreting gastric mucosa with a mildly abnormal architecture comprising irregular pits lined by epithelium showing reactive changes. Within the lamina propria there is a moderately dense infiltrate of lymphocytes and plasma cells along with small numbers of neutrophils. Focally, neutrophils are seen infiltrating surface and crypt epithelium. Numerous *Helicobacter pylori* are seen colonising surface and crypt mucin. There is no evidence of gland atrophy, intestinal metaplasia or epithelial dysplasia.

2. There are multiple fragments of non-acid secreting gastric mucosa along with fragments of inflamed granulation tissue, consistent with origin from an ulcer base. The fragments of gastric mucosa comprise irregular pits lined by epithelium showing reactive changes and with moderate complete and incomplete intestinal metaplasia. The lamina propria contains a moderately dense infiltrate of lymphocytes and plasma cells along with smaller numbers of neutrophils. Focally neutrophils are seen infiltrating surface and pit epithelium. Small numbers of *Helicobacter pylori* are seen colonising surface and crypt mucin.

Within the fragments of inflamed granulation tissue, there are irregular cords and clusters of cells, focally with poorly formed glands, with enlarged pleomorphic hyperchromatic nuclei, frequent mitoses and a moderate amount of eosinophilic cytoplasm. Occasional cells have a signet-ring morphology and mucin stains shows focal Alcian blue and PASD positive mucin.

The features are those of a mildly active moderate chronic *Helicobacter*-associated gastritis involving body and antrum as well as an ulcerated poorly differentiated adenocarcinoma.

3. There is a fragment of large bowel mucosa with a normal tubular

HISTOLOGY

ANATOMICAL PATH

[page 2 of 3]
Patient Location

Name

Given Name

DOB

Patient Address

Consultant

Sex M

Tel:

FILE IN PATIENT HISTORY

HISTOPATHOLOGY REPORT

Biopsy No

Received

Lab No

Collected

architecture and showing mild diathermy artefact. The epithelium is unremarkable. The lamina propria contains a chronic inflammatory cell infiltrate within normal limits along with small numbers of neutrophils and rare pigment laden macrophages. There is no evidence of epithelial dysplasia or malignancy.

The features are those of large bowel mucosa showing mild non-specific active inflammation.

DIAGNOSIS

1. Gastric bx: Mildly active moderate chronic Helicobacter-associated gastritis.
2. Gastric tumour:
- a) Poorly differentiated adenocarcinoma.
- b) Mildly active moderate chronic Helicobacter-associated gastritis with intestinal metaplasia.
3. Ascending colon polyp: Mild non-specific inflammatory changes.

TSS diagnostic discrepancy from
Staten TGA tumor to be
adenocarcinoma, intestinal type

Criteria	10/8/13	Yes	No
HPV Discrepancy			✓
Dual/Syn. In situ Primary Note			
Reviewed this	10/7/2013		

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	adenocarcinoma, NOS	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	adenocarcinoma intestinal type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Subtype classification not specified in pathology report	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file e56510d4-d987-4f35-9980-3ff3bcd8a997 (TCGA-RD-A8MW.3365620C-1C4E-4E1A-8B53-38CD26B6651C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).